Gene-level copy-number profile of tumor specimen C3L-05556-01 from CPTAC case C3L-05556, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.1 years (25,964 days).
Specimen C3L-05556-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c5dbd436-a216-461c-aed0-1f3d1af8dd83.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05556-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,244 have no estimate.
https://portal.gdc.cancer.gov/files/4f941056-0eaa-4548-94b6-b2ac2ccbc7fd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 5,912; copy number 2: 38,601; copy number 3: 8,733; copy number 4: 3,714; copy number 5: 252; copy number 6: 894; copy number 7: 92; copy number 8: 176.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,473,351–248,527,337, 5 genes: OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,414 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,288,596–146,914,294, 10 genes, copy number 5: RNU6-1071P, NUDT4P2, SEC22B4P, PPIAL4H, RNVU1-29, RNVU1-25, AC245407.1, HYDIN2, RNA5SP536, AC241929.1.
- chr1:149,754,301–153,205,120, 192 genes, copy number 6–8 (broad region; genes not listed).
- chr1:153,416,520–155,739,010, 143 genes, copy number 6 (broad region; genes not listed).
- chr1:159,171,609–163,509,595, 174 genes, copy number 5–8 (broad region; genes not listed).
- chr1:165,201,867–166,167,001, 29 genes, copy number 6: LMX1A, LMX1A-AS2, LMX1A-AS1, RXRG, LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1, AL451074.4, UCK2, AL358115.1, MIR3658, AL606495.1, RPS3AP10, RNA5SP64, FAM78B, FAM78B-AS1, AL596087.3, MIR921.
- chr1:166,895,711–173,207,331, 142 genes, copy number 5–7 (broad region; genes not listed).
- chr1:173,931,084–174,022,357, 1 gene, copy number 6 (within-gene range 4–6): RC3H1.
- chr1:174,009,267–174,090,474, 3 genes, copy number 6: RC3H1-IT1, LINC02776, RPL30P1.
- chr1:184,690,237–185,657,168, 27 genes, copy number 5: EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1.
- chr1:191,179,521–194,198,708, 33 genes, copy number 6–7: AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031, AL136456.1, AL357793.1, AL357793.2, RPL23AP22, EEF1A1P14.
- chr1:198,523,222–198,937,471, 8 genes, copy number 5: ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1.
- chr1:200,253,419–200,400,705, 1 gene, copy number 6 (within-gene range 4–6): LINC00862.
- chr1:200,333,193–201,829,559, 38 genes, copy number 5–6: AC104461.1, ZNF281, AL359834.1, KIF14, DDX59, DDX59-AS1, CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, TNNI1, AC096677.3, PHLDA3, AC096677.2, CSRP1, AC096677.1, RPS10P7, NAV1, AC092800.1, IPO9-AS1, MIR5191, AL645504.1, RNU6-501P, MIR1231.
- chr1:204,822,664–206,869,223, 65 genes, copy number 5 (broad region; genes not listed).
- chr1:243,917,402–244,109,011, 7 genes, copy number 5: LINC02774, ZBTB18, AL590483.3, AL590483.1, AL590483.4, RN7SL148P, AL590483.2.
- chr1:248,936,581–248,937,043, 1 gene, copy number 5: RPL23AP25.
- chr21:17,431,547–26,171,128, 110 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr21:30,425,265–40,847,158, 246 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr21:40,736,318–40,754,888, 1 gene, copy number 6: AF064866.1.
- chr22:16,921,443–20,704,606, 183 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,912. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
